Somatic mutation profile of tumor specimen ALCH-B4BI-TTP1-A (aliquot ALCH-B4BI-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4BI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 73.6 years (26,875 days).
Specimen ALCH-B4BI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5915861b-8e13-45f1-97d8-d81b3b7c103c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4BI-NB1-A (Blood Derived Normal), aliquot ALCH-B4BI-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2277937-d4ff-434a-af8b-8b3f2253a757

The open-access MAF lists 214 somatic variants for this specimen: 146 protein-altering or splice-affecting, 45 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 45, Nonsense Mutation 20, Intron 11, Frame Shift Del 5, RNA 5, 3'UTR 3, Splice Region 3, 5'Flank 3, Splice Site 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 87/298 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 44/313 reads (14%) | catalogued as COSV55944684; called by muse, mutect2, varscan2
- ADGRL3 | c.3781G>T p.G1261* (on ENST00000506720 / NM_001322402.2; = p.G1193* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 19/230 reads (8%) | catalogued as COSV72229458; called by muse, mutect2
- ADH7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs773461976; called by muse, mutect2
- AGAP1 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs376740199; called by muse, mutect2, varscan2
- AMER3 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV58465000; called by muse, mutect2, varscan2
- ATP10D | c.3707C>T p.A1236V | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs769868948; called by muse, mutect2, varscan2
- CACNA1E | c.619C>T p.L207= | Splice Region (SNP) | VAF 6/64 reads (9%) | catalogued as rs1558147600; called by muse, mutect2
- CATSPER4 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV58792571; called by muse, mutect2, varscan2
- CD6 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as rs764381085, COSV100533129; called by muse, mutect2, varscan2
- CEP350 | c.7054G>T p.E2352* | Nonsense Mutation (SNP) | VAF 45/172 reads (26%) | catalogued as COSV62602197, COSV62604502; called by muse, mutect2, varscan2
- CFAP65 | c.645G>A p.A215= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as rs757806079; called by muse, mutect2, varscan2
- COL11A1 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 35/463 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1280999450; called by muse, mutect2
- COL11A1 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 37/473 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62177557; called by muse, mutect2
- CRYGA | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100378531; called by muse, mutect2
- DMRTA1 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100364596; called by muse, mutect2, varscan2
- FLG | c.4546G>C p.G1516R | Missense Mutation (SNP) | VAF 20/517 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.97); catalogued as COSV100911945; called by muse, mutect2
- FYTTD1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as COSV54081819; called by muse, mutect2
- GABRG1 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954480, COSV54960971, COSV99777223; called by muse, mutect2
- GABRG1 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV54959931; called by muse, mutect2
- GC | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV56740095, COSV99909514; called by muse, mutect2, varscan2
- GLI2 | c.2981G>A p.S994N (on ENST00000361492 / NM_001374353.1; = p.S1011N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1400437764; called by muse, mutect2, varscan2
- HCN1 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV57495408; called by muse, mutect2, varscan2
- HTR1A | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.802); catalogued as COSV100109322; called by muse, mutect2, varscan2
- IARS1 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200389880; called by muse, mutect2, varscan2
- IGFBP7 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1024087414; called by muse, mutect2, varscan2
- IGHJ1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 57/371 reads (15%) | catalogued as rs782334998; called by muse, mutect2, varscan2
- KCND2 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.627); catalogued as rs749225363, COSV58580826; called by muse, mutect2
- KSR2 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV56667008; called by muse, mutect2, varscan2
- LRRN1 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60016666; called by muse, mutect2, varscan2
- MAGEB5 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs754656027, COSV66869124; called by muse, mutect2
- MAPK8IP2 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs760111333; called by muse, mutect2, varscan2
- MUS81 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416645763, COSV57260331; called by muse, mutect2, varscan2
- NEB | c.15894+1G>T p.X5298_splice | Splice Site (SNP) | VAF 9/107 reads (8%) | catalogued as COSV99427029; called by muse, mutect2
- NNT | c.3066dup p.I1023Yfs*9 | Frame Shift Ins (INS) | VAF 20/218 reads (9%) | catalogued as rs1196459045; called by mutect2, pindel
- NPAS3 | c.1681G>A p.V561M (on ENST00000356141 / NM_001164749.2; = p.V529M on NM_022123.3) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs769204359; called by muse, mutect2, varscan2
- NT5DC3 | c.1077G>T p.L359F | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.371); catalogued as COSV101230957; called by muse, mutect2, varscan2
- NTNG2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62366763; called by muse, mutect2, varscan2
- OPN5 | c.545C>A p.S182* | Nonsense Mutation (SNP) | VAF 26/155 reads (17%) | catalogued as COSV55244010; called by muse, mutect2, varscan2
- OR10A5 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1468144023; called by muse, mutect2, varscan2
- OR4N2 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100269768; called by muse, varscan2
- PCDHA11 | c.1607C>A p.A536E | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56485376, COSV56535321; called by muse, mutect2, varscan2
- PCDHA3 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 63/479 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV63538847; called by muse, mutect2, varscan2
- PCGF6 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs1245925931; called by muse, varscan2
- PLD1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434314217, COSV60566110, COSV60571560; called by muse, mutect2
- PPP4R3C | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1569128313, COSV69080776; called by muse, mutect2, varscan2
- PSG4 | c.500T>A p.L167* | Nonsense Mutation (SNP) | VAF 44/256 reads (17%) | catalogued as COSV99736855; called by muse, mutect2, varscan2
- RNF213 | c.12811G>T p.E4271* | Nonsense Mutation (SNP) | VAF 43/350 reads (12%) | catalogued as COSV60393936; called by muse, mutect2, varscan2
- RPE65 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 40/324 reads (12%) | catalogued as COSV52016372; called by muse, mutect2, varscan2
- RXFP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100313968, COSV57046929; called by muse, mutect2
- RYR2 | c.10812del p.M3605Wfs*36 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as COSV63692889, COSV63714903; called by mutect2, pindel, varscan2
- SH3GL2 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66053514; called by muse, varscan2
- SLC39A12 | c.1910C>A p.T637N (on ENST00000377369 / NM_001145195.2; = p.T600N on NM_152725.3) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66197983; called by muse, mutect2, varscan2
- SMC2 | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 21/155 reads (14%) | catalogued as COSV53958001; called by muse, mutect2
- SMCO3 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.6); catalogued as COSV53762472; called by muse, mutect2, varscan2
- SRP68 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757149057, COSV57161641; called by muse, mutect2, varscan2
- TASOR | c.3805G>A p.V1269I (on ENST00000355628 / NM_001365636.2; = p.V893I on NM_015224.3) | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs756047419; called by muse, mutect2, varscan2
- TBXT | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV51620838; called by muse, mutect2
- UHRF1BP1L | c.3592A>G p.T1198A | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs765212378; called by muse, mutect2, varscan2
- UNC13A | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53189718; called by muse, mutect2, varscan2
- VPS13D | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV62531938; called by muse, mutect2
- ZDHHC18 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as rs762413704; called by muse, mutect2, varscan2
- ZNF124 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149904613; called by muse, mutect2, varscan2
- ZNF536 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62821835; called by muse, mutect2, varscan2
- ABCA13 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCA5 | c.2457G>A p.M819I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC024598.1 | c.1106G>T p.W369L | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB2 | c.2113G>T p.V705L | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- AIM2 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ARHGAP24 | c.412G>C p.E138Q (on ENST00000395184 / NM_001025616.3; = p.E45Q on NM_031305.3) | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BLNK | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BSN | c.5289G>T p.Q1763H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BTBD16 | c.662A>T p.Y221F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CCKBR | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CLEC4M | c.704A>G p.K235R | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.587); called by muse, varscan2
- CRX | c.227T>A p.I76N | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD2 | c.6802G>A p.V2268I | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CSMD3 | c.2861G>T p.G954V (on ENST00000297405 / NM_001363185.1; = p.G850V on NM_052900.3) | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAI4 | c.1495-2A>T p.X499_splice | Splice Site (SNP) | VAF 38/352 reads (11%) | called by muse, mutect2, varscan2
- DNM3 | c.1552A>T p.N518Y | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- DPP7 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- EPS8L2 | c.1259A>T p.H420L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBN2 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- FCGR2B | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- FSTL3 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GJA4 | c.65del p.G22Vfs*5 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- GOLGA5 | c.1915_1919del p.I639Yfs*5 | Frame Shift Del (DEL) | VAF 32/220 reads (15%) | called by mutect2, pindel, varscan2
- GPD2 | c.1010A>T p.D337V | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN1 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGSF9B | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ILDR2 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- ILDR2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- JAK1 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- JAKMIP1 | c.1664A>T p.E555V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KIDINS220 | c.4273G>A p.G1425S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LMO1 | c.273C>A p.C91* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- MEF2C | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MEP1B | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MORC1 | c.1214T>A p.L405* | Nonsense Mutation (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- NCCRP1 | c.728T>A p.F243Y | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.082); called by muse, mutect2
- NUBP1 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NUP160 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OLFML2A | c.300T>A p.C100* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | called by muse, mutect2, varscan2
- OR9G4 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OVOL1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- P2RX7 | c.120C>A p.Y40* | Nonsense Mutation (SNP) | VAF 95/241 reads (39%) | called by muse, mutect2, varscan2
- PBX1 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, varscan2
- PCDHGB7 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PCSK4 | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLCB4 | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- PPM1L | c.1006T>C p.F336L | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- PRSS58 | c.313A>T p.I105F | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTEN | c.1026+4A>T | Splice Region (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- PTGR2 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- PTPN13 | c.7198A>T p.R2400* (on ENST00000411767 / NM_080683.3; = p.R2381* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 43/322 reads (13%) | called by muse, mutect2, varscan2
- QRFP | c.369C>A p.S123R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RAD51AP2 | c.2250T>G p.N750K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RBM10 | c.914G>C p.R305P | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RFX8 | c.436G>T p.D146Y (on ENST00000646446; = p.D75Y on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- RIPK2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN10A | c.2201G>T p.C734F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SEL1L2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- SH3RF3 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SIGLEC10 | c.854C>A p.T285K | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SLC18A2 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC8A1 | c.2812G>A p.G938S | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK3 | c.920C>A p.P307Q | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SP7 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31A7 | c.1043del p.G348Dfs*7 | Frame Shift Del (DEL) | VAF 46/388 reads (12%) | called by mutect2, varscan2
- SSX3 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STAM | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2
- TCF7L2 | c.1102G>C p.V368L (on ENST00000355995 / NM_001367943.1; = p.V345L on NM_030756.5) | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TDRD15 | c.3013C>A p.Q1005K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBI | c.572T>A p.L191H | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TNIP3 | c.579G>C p.M193I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2
- TRIM49B | c.522A>T p.L174F | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TRPA1 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPV3 | c.1825A>T p.I609F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TTC39B | c.762T>A p.D254E | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- TUBGCP3 | c.2255A>T p.E752V | Missense Mutation (SNP) | VAF 25/269 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2
- USH2A | c.14140G>A p.A4714T | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- UTRN | c.2260A>T p.I754F | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2
- VPS4B | c.418del p.E140Kfs*7 | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | called by mutect2, pindel, varscan2
- WDR87 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF418 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- ZNF711 | c.1944G>T p.Q648H | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- ADAMTS16 | c.147G>A p.A49= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as rs1350979915; called by muse, mutect2
- AL136295.1 | c.1926T>C p.F642= | Silent (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- ANKRD12 | c.255A>C p.T85= | Silent (SNP) | VAF 42/294 reads (14%) | called by muse, mutect2, varscan2
- ASB14 | c.1305C>A p.V435= | Silent (SNP) | VAF 19/264 reads (7%) | called by muse, mutect2
- BIVM-ERCC5 | c.4872G>T p.G1624= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- CDH5 | c.873G>T p.R291= | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- CNGA3 | c.1695G>T p.T565= | Silent (SNP) | VAF 79/488 reads (16%) | catalogued as COSV55624402; called by muse, mutect2, varscan2
- CNTNAP5 | c.2104C>A p.R702= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV70472432, COSV70483251; called by muse, mutect2, varscan2
- CR1L | c.1566C>A p.I522= | Silent (SNP) | VAF 28/410 reads (7%) | catalogued as COSV54325638; called by muse, mutect2
- DDX51 | c.940C>T p.L314= | Silent (SNP) | VAF 83/212 reads (39%) | catalogued as rs749140549, COSV100223173; called by muse, mutect2, varscan2
- DISP2 | c.648C>A p.V216= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- EPPK1 | c.4950C>T p.T1650= | Silent (SNP) | VAF 52/270 reads (19%) | catalogued as rs550287920; called by muse, mutect2, varscan2
- ERC1 | c.1191G>T p.G397= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- EVX2 | c.843C>T p.H281= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- FANCM | c.867T>G p.L289= | Silent (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- FARP2 | c.282C>G p.S94= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- FCRL6 | c.480C>T p.G160= | Silent (SNP) | VAF 12/187 reads (6%) | catalogued as COSV58941077; called by muse, mutect2
- FXYD4 | c.12G>T p.V4= | Silent (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- GLRA3 | c.1269C>T p.D423= | Silent (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- HTRA4 | c.261G>T p.P87= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.102T>G p.S34= | Silent (SNP) | VAF 43/382 reads (11%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.12T>A p.A4= | Silent (SNP) | VAF 26/246 reads (11%) | called by muse, varscan2
- ITIH5 | c.747T>C p.I249= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- KCNV1 | c.903G>T p.T301= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV99819472; called by muse, mutect2, varscan2
- KRTAP1-3 | c.330C>G p.R110= | Silent (SNP) | VAF 33/277 reads (12%) | called by muse, mutect2, varscan2
- LYST | c.210A>G p.E70= | Silent (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- MAGEC3 | c.1026C>A p.V342= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2, varscan2
- MAP3K10 | c.1737G>A p.L579= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1568494348; called by muse, mutect2, varscan2
- OR2T12 | c.552T>A p.R184= | Silent (SNP) | VAF 47/403 reads (12%) | catalogued as COSV58777954; called by muse, mutect2, varscan2
- PID1 | c.6C>T p.F2= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PLCH1 | c.1818G>T p.V606= (on ENST00000340059 / NM_001130960.2; = p.V618= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.711C>A p.L237= | Silent (SNP) | VAF 55/445 reads (12%) | catalogued as COSV60020349; called by muse, mutect2, varscan2
- RIPK2 | c.90C>A p.G30= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV55134675; called by muse, mutect2, varscan2
- SH2D4B | c.837G>A p.P279= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1315826071, COSV57898411; called by muse, mutect2, varscan2
- SH3RF3 | c.1677G>A p.L559= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs765140856, COSV58695098; called by muse, mutect2, varscan2
- SHBG | c.612C>T p.A204= | Silent (SNP) | VAF 34/308 reads (11%) | catalogued as rs148740302; called by muse, mutect2, varscan2
- SLC6A11 | c.111C>A p.R37= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- SMCO3 | c.477C>A p.L159= | Silent (SNP) | VAF 81/296 reads (27%) | catalogued as COSV53761571; called by muse, mutect2, varscan2
- TBK1 | c.1044A>T p.S348= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- TMEM102 | c.1161G>T p.A387= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- TMEM132C | c.996G>T p.V332= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- TMEM43 | c.117G>T p.G39= | Silent (SNP) | VAF 39/224 reads (17%) | called by muse, mutect2, varscan2
- TXK | c.741G>C p.G247= | Silent (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- WDR59 | c.2574A>G p.Q858= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs769329278; called by muse, mutect2, varscan2
- ZNF830 | c.573G>A p.E191= | Silent (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2
- CLCN7 | c.*322C>T | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- CSF2RA | c.647-17C>A | Intron (SNP) | VAF 45/269 reads (17%) | called by muse, mutect2, varscan2
- DYM | c.1860+20G>A | Intron (SNP) | VAF 30/463 reads (6%) | called by muse, mutect2
- FOXP3 | c.1147-14C>A | Intron (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-1005C>T | Intron (SNP) | VAF 14/132 reads (11%) | catalogued as rs1200485513; called by muse, mutect2, varscan2
- GLRXP3 | n.49G>T | RNA (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- HERC2P3 | n.735A>T | RNA (SNP) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- HOXB4 | chr17:48579938 C>A | 5'Flank (SNP) | VAF 62/355 reads (17%) | called by muse, mutect2, varscan2
- KANK2 | c.1418-17G>C | Intron (SNP) | VAF 14/117 reads (12%) | catalogued as COSV62006785; called by muse, mutect2
- KCNC4 | c.*587G>T | 3'UTR (SNP) | VAF 56/382 reads (15%) | catalogued as COSV63925706; called by muse, mutect2, varscan2
- LDLR | c.1359-29G>C | Intron (SNP) | VAF 46/264 reads (17%) | called by muse, mutect2, varscan2
- LINC01546 | n.472C>A | RNA (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- LRRC69 | c.184-6222G>A | Intron (SNP) | VAF 16/106 reads (15%) | catalogued as rs1429105657; called by muse, mutect2, varscan2
- NDUFAF6 | c.-249C>T | 5'UTR (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- NORAD | n.417C>T | RNA (SNP) | VAF 20/61 reads (33%) | catalogued as rs775984766; called by muse, mutect2, varscan2
- PAX5 | c.781-7454C>A | Intron (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- PKD1L1 | c.7174-237C>A | Intron (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1390+463del | Intron (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- RBM34 | chr1:235161331 del CGCCGGGCGGCGGCGAAGGGAGG | 5'Flank (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- SVIL2P | n.1602G>T | RNA (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- XIRP2 | c.*1430G>T | 3'UTR (SNP) | VAF 38/302 reads (13%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451213 C>T | 5'Flank (SNP) | VAF 7/51 reads (14%) | catalogued as COSV56514141; called by muse, mutect2, varscan2
- ZNF99 | c.4-632A>C | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs1462542531, COSV101233866; called by muse, mutect2, varscan2
